Somatic mutation profile of tumor specimen TCGA-55-A493-01A (aliquot TCGA-55-A493-01A-11D-A24D-08) from TCGA case TCGA-55-A493, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.8 years (20,027 days).
Specimen TCGA-55-A493-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ff85c14-6433-4173-bfa1-2214d92a6482.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A493-10A (Blood Derived Normal), aliquot TCGA-55-A493-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e44c528-4c1a-4707-984f-a976c433628f

The open-access MAF lists 276 somatic variants for this specimen: 197 protein-altering or splice-affecting, 75 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 75, Nonsense Mutation 16, Frame Shift Del 7, Splice Site 5, Splice Region 2, Intron 1, RNA 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCC2 | c.2390A>C p.K797T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100966434; called by muse, mutect2, varscan2
- ABCG8 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99699551; called by muse, mutect2
- ADAM15 | c.1375G>T p.A459S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV99664822; called by muse, mutect2, varscan2
- ADGRL3 | c.2457G>T p.L819F (on ENST00000506720 / NM_001322402.2; = p.L751F on NM_015236.6) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101546929; called by muse, mutect2, varscan2
- ALPK1 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99453436; called by muse, mutect2, varscan2
- AMER3 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100366193; called by muse, mutect2, varscan2
- AMY1A | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs769271241, COSV64410921; called by muse, mutect2, varscan2
- ANK2 | c.5385G>T p.E1795D | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs777568337, COSV100000451; called by muse, mutect2, varscan2
- ANK2 | c.5996C>T p.S1999L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV100000453; called by muse, mutect2, varscan2
- ARC | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.432); catalogued as rs762668132, COSV63078481; called by muse, varscan2
- ARL2BP | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99535991; called by muse, mutect2
- ARSK | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.908); catalogued as COSV101187530; called by muse, mutect2, varscan2
- ASAP1 | c.2989G>T p.D997Y | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.343); catalogued as COSV100726976; called by muse, mutect2
- ATP2B3 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as rs782008053, COSV54847756; called by muse, mutect2
- ATP6V1E2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100120712; called by muse, mutect2
- ATP8B2 | c.691G>A p.E231K (on ENST00000672630; = p.E198K on NM_001005855.2) | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.713); catalogued as COSV100527789; called by muse, mutect2, varscan2
- B3GNT2 | c.369G>C p.L123F | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV100114080; called by muse, mutect2
- B3GNT2 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.745); catalogued as COSV100114082; called by muse, mutect2, varscan2
- BCDIN3D | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100445484; called by muse, mutect2
- BEST3 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV99876127; called by muse, mutect2
- C1QB | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152720, COSV59245358; called by muse, mutect2, varscan2
- C1R | c.875C>T p.T292I (on ENST00000536053 / NM_001354346.2; = p.T278I on NM_001733.7) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV101599215; called by muse, mutect2
- C5orf51 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101068900, COSV67565726; called by muse, mutect2, varscan2
- C8orf34 | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV61386831; called by muse, mutect2
- CA14 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs782776922, COSV99354309; called by muse, mutect2, varscan2
- CCDC197 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100113622; called by muse, mutect2, varscan2
- CCDC85A | c.901A>T p.S301C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV101339419; called by muse, mutect2, varscan2
- CDC25C | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV100086579; called by muse, mutect2, varscan2
- CDH12 | c.98C>A p.T33K | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101201898; called by muse, mutect2, varscan2
- CDH17 | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV99217112; called by muse, mutect2, varscan2
- CDH17 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 19/109 reads (17%) | catalogued as COSV99217119; called by muse, mutect2, varscan2
- CEACAM8 | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99747487; called by muse, mutect2, varscan2
- CHP1 | c.472A>T p.R158W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100587028; called by muse, mutect2, varscan2
- CHRNG | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs140462342; called by mutect2, varscan2
- CKAP5 | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.202); catalogued as COSV100370574; called by muse, mutect2, varscan2
- CLC | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV99695566; called by muse, mutect2
- CLEC12A | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100429426, COSV58562492; called by muse, mutect2
- CNTN3 | c.2885T>A p.L962H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99723736; called by muse, mutect2, varscan2
- CSMD3 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52289346; called by muse, mutect2
- CTNNA2 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.027); catalogued as COSV100559689; called by muse, mutect2, varscan2
- CYP26B1 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as rs764651607, COSV50010989; called by muse, mutect2, varscan2
- DNAJC6 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV99674345; called by muse, mutect2, varscan2
- DOP1B | c.1370G>T p.R457I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV101215166; called by mutect2, varscan2
- DYNC2H1 | c.2491A>G p.R831G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs894877792, COSV100517951; called by muse, mutect2, varscan2
- DYSF | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99245366; called by muse, mutect2
- EFCAB6 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs750645986, COSV99412795; called by muse, mutect2, varscan2
- ELMOD1 | c.391A>T p.N131Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99759745; called by mutect2, varscan2
- ELOA2 | c.206T>A p.L69* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99796185; called by muse, mutect2, varscan2
- EPN1 | c.1661G>T p.G554V (on ENST00000270460 / NM_001321263.1; = p.G528V on NM_013333.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99321703; called by muse, mutect2
- ERGIC2 | c.649A>T p.I217L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100791949; called by muse, mutect2, varscan2
- F11 | c.1610T>C p.I537T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV99250735; called by muse, mutect2
- FAM53C | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99524280; called by muse, mutect2, varscan2
- FDPS | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV52740971, COSV99429591; called by muse, mutect2
- FILIP1 | c.1958T>G p.L653W | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99384179; called by muse, mutect2
- FRY | c.8976G>T p.R2992S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as COSV100968927; called by muse, mutect2, varscan2
- FZD10 | c.440G>C p.C147S | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969310; called by muse, mutect2
- GAK | c.2974G>T p.V992F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV100033315, COSV58510687; called by muse, mutect2, varscan2
- GPR6 | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs898785367, COSV51571702, COSV99254150; called by muse, mutect2, varscan2
- GPR84 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99909978, COSV99910164; called by muse, mutect2, varscan2
- GREB1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs372268268, COSV52191820; called by muse, mutect2, varscan2
- GREB1 | c.3416C>T p.S1139L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99302461; called by muse, varscan2
- GRM1 | c.3257G>T p.G1086V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99264891; called by muse, mutect2, varscan2
- HDAC4 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100612930; called by muse, mutect2, varscan2
- HEPHL1 | c.2232G>C p.W744C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243698; called by muse, mutect2
- HIVEP2 | c.3893C>T p.P1298L | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs1365228482, COSV99171611; called by muse, mutect2, varscan2
- HSD17B14 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV99622685; called by muse, mutect2, varscan2
- ICE1 | c.3713C>T p.S1238L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV56828994; called by muse, mutect2
- IGF2BP2 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV100648931; called by muse, mutect2, varscan2
- ITIH2 | c.1719G>T p.K573N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as rs376261360, COSV100623220; called by mutect2, varscan2
- KAT6B | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99767600; called by muse, mutect2, varscan2
- KCNN4 | c.1049+1G>T p.X350_splice | Splice Site (SNP) | VAF 20/105 reads (19%) | catalogued as COSV53457479, COSV99486974; called by muse, varscan2
- KCNV2 | c.1177C>G p.H393D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101172542; called by muse, mutect2, varscan2
- KIDINS220 | c.4144G>T p.E1382* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99875270; called by muse, mutect2
- KIF13B | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101580559; called by muse, mutect2, varscan2
- KIF2B | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV99274943; called by muse, mutect2
- KIF4B | c.2075A>T p.N692I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV101469217; called by muse, mutect2, varscan2
- KRT33A | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs768092751, COSV50375186; called by muse, mutect2
- KRT82 | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1440687888, COSV99233452; called by muse, mutect2, varscan2
- LAMA3 | c.3648A>G p.I1216M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs1251977597, COSV100555866; called by muse, mutect2, varscan2
- LAMB4 | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV99223303; called by muse, mutect2, varscan2
- LAP3 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as COSV99884135; called by muse, mutect2
- LGI4 | c.1266C>A p.F422L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100032353; called by muse, mutect2, varscan2
- LTBR | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs1029284604, COSV99965224; called by muse, mutect2, varscan2
- LY6D | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100009251; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51718046; called by muse, mutect2, varscan2
- MUC3A | c.8015C>T p.A2672V | Missense Mutation (SNP) | VAF 55/480 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); catalogued as rs939732727, COSV100114220; called by muse, varscan2
- NFIA | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as COSV100963531; called by muse, mutect2, varscan2
- NLRP10 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100149551, COSV60779160; called by muse, mutect2
- NPAP1 | c.522C>A p.D174E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as rs368120585, COSV100274980; called by mutect2, varscan2
- NPPC | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.737); catalogued as COSV99776634; called by muse, mutect2, varscan2
- NPTXR | c.1052T>A p.L351Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285399; called by muse, mutect2
- NRP2 | c.1116G>C p.W372C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99783741; called by muse, mutect2, varscan2
- NTSR1 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1158106892, COSV65139663; called by muse, mutect2, varscan2
- NUDT3 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101466189; called by muse, mutect2
- NUP205 | c.1871G>A p.W624* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV53657962, COSV99606642; called by muse, mutect2
- NUP210 | c.4968G>T p.K1656N | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV99595794; called by muse, mutect2, varscan2
- OR2G2 | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV100189655; called by muse, mutect2
- OR2G6 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV100598064; called by muse, mutect2
- OR7D4 | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100432635; called by muse, mutect2
- OR8K5 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100537174, COSV57890023; called by muse, mutect2
- OSR1 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99693580; called by muse, mutect2, varscan2
- PACS1 | c.805+1G>A p.X269_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV57698259; called by muse, mutect2, varscan2
- PADI2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100971843; called by muse, mutect2, varscan2
- PALB2 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs45602040; ClinVar: uncertain significance; called by muse, mutect2
- PCDH12 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV99186496; called by muse, mutect2, varscan2
- PCDHA2 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201558063; called by muse, mutect2, varscan2
- PCDHGA3 | c.1233C>A p.D411E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99533743; called by muse, mutect2, varscan2
- PCDHGA3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs770576379, COSV99533745, COSV99540825; called by muse, mutect2, varscan2
- PCDHGA5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV53920326, COSV53955956; called by muse, mutect2, varscan2
- PCDHGB1 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs760271009, COSV99533747; called by muse, mutect2, varscan2
- PCDHGB6 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1485327824, COSV99533749; called by muse, mutect2, varscan2
- PEG3 | c.2684T>C p.V895A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99687931; called by muse, mutect2, varscan2
- PI4K2A | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101034141; called by muse, varscan2
- PKHD1 | c.4309G>C p.G1437R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100581933; called by muse, mutect2, varscan2
- PLAAT4 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV99737628; called by muse, mutect2, varscan2
- PLOD1 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.264); catalogued as rs372534520, COSV99537970; called by muse, mutect2, varscan2
- POMZP3 | c.333C>A p.D111E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.859); catalogued as COSV99300372; called by mutect2, varscan2
- PPIE | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100179985; called by muse, mutect2, varscan2
- PPP1R13L | c.2274G>C p.M758I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100714695; called by muse, mutect2, varscan2
- PRB3 | c.693A>T p.Q231H (on ENST00000381842; = p.Q273H on NM_006249.5) | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.64); catalogued as COSV54388261, COSV99685582; called by muse, mutect2
- PRDM15 | c.1691G>T p.R564L | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs756946493, COSV54156531; called by muse, mutect2, varscan2
- PSG1 | c.798T>A p.S266R | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99739240; called by muse, mutect2, varscan2
- PSG8 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.555); catalogued as COSV100126055; called by muse, mutect2, varscan2
- RAD51AP2 | c.2123G>C p.C708S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101208305; called by mutect2, varscan2
- RBM12 | c.1584G>C p.Q528H | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100467222; called by muse, mutect2, varscan2
- RCBTB2 | c.784-1G>T p.X262_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as rs369058000; called by muse, mutect2, varscan2
- REG1A | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.58); catalogued as COSV99286702; called by muse, mutect2, varscan2
- RFTN2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774363692, COSV54387152; called by muse, mutect2, varscan2
- RNF207 | c.1797G>A p.W599* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100658235; called by muse, mutect2, varscan2
- RNF213 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100173225; called by muse, mutect2
- RPL10A | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100003244; called by muse, mutect2, varscan2
- RXFP3 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100347414, COSV57506243; called by muse, mutect2, varscan2
- SAMD9L | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs142436298, COSV100560484; called by muse, mutect2
- SCAF11 | c.3731G>T p.R1244L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs762262046, COSV101014148, COSV65475310; called by muse, mutect2, varscan2
- SCFD2 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as COSV66374132; called by muse, mutect2, varscan2
- SCN9A | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.606); catalogued as COSV100311970; called by muse, mutect2
- SDCCAG8 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100654000; called by muse, mutect2, varscan2
- SFTPA1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV64867725; called by muse, mutect2
- SHROOM2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV101098329; called by muse, mutect2
- SLC12A7 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99369525; called by muse, mutect2, varscan2
- SLC18A3 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100339933; called by muse, mutect2
- SLC35F1 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV100837676; called by muse, mutect2
- SLC44A1 | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.166); catalogued as COSV100570270; called by muse, mutect2, varscan2
- SLC44A5 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100901486, COSV63770823; called by muse, mutect2
- SLC9C1 | c.3235C>T p.Q1079* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99997562; called by muse, mutect2, varscan2
- SMARCA1 | c.3038A>T p.Q1013L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100946434; called by mutect2, varscan2
- SMC1B | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs769894807, COSV62530515; called by muse, mutect2, varscan2
- SPIDR | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99854494; called by muse, mutect2, varscan2
- SRP68 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100326005; called by muse, mutect2
- SRSF2 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100333608; called by muse, mutect2
- TANC1 | c.4068G>C p.E1356D | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55098669, COSV99713349; called by muse, mutect2
- THEMIS2 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100197939; called by muse, mutect2, varscan2
- TIAM1 | c.1253G>T p.S418I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs761754794; called by muse, mutect2
- TMPRSS15 | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99517307; called by muse, mutect2, varscan2
- TRMT2B | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100105254; called by muse, mutect2, varscan2
- TRMT61B | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100066387; called by muse, mutect2, varscan2
- TRPV1 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV99439009; called by muse, mutect2, varscan2
- TTN | c.13330A>G p.R4444G (on ENST00000591111; = p.R4398G on NM_003319.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | PolyPhen benign (0.083); catalogued as COSV100600812; called by muse, mutect2, varscan2
- TXLNB | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV100624879; called by muse, mutect2
- UBQLN2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100592651; called by muse, mutect2, varscan2
- URB2 | c.306C>T p.I102= | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as rs1390955773, COSV99270862; called by muse, mutect2
- USH2A | c.5348C>A p.A1783D | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.187); catalogued as COSV100231488, COSV56414582; called by muse, mutect2
- VPS13B | c.4821-2A>G p.X1607_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100661269; called by muse, mutect2, varscan2
- VSTM4 | c.788C>G p.P263R | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100251439, COSV60524805; called by muse, mutect2
- WDR45B | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101124421, COSV66408248; called by muse, mutect2, varscan2
- WDR49 | c.949C>A p.H317N (on ENST00000308378 / NM_001366158.1; = p.H658N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV100392076; called by mutect2, varscan2
- WIPF1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181632515, COSV55816968, COSV99768236; called by muse, mutect2, varscan2
- ZC3H13 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV54448585; called by muse, mutect2
- ZMAT4 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as COSV99909084; called by muse, mutect2, varscan2
- ZNF222 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs200027663, COSV99496184; called by muse, mutect2, varscan2
- ZNF236 | c.4693G>A p.A1565T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.413); catalogued as rs372028039; called by mutect2, varscan2
- ZNF366 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV59213941, COSV59215138; called by muse, mutect2
- ZNF425 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750464069, COSV100955424; called by muse, mutect2, varscan2
- ZNF552 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as rs1024661858, COSV99063435; called by muse, mutect2
- ZNF568 | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100451220; called by muse, mutect2, varscan2
- ZNF585A | c.835T>G p.F279V (on ENST00000292841 / NM_001288800.2; = p.F224V on NM_152655.3) | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492878, COSV99493298; called by muse, mutect2
- ZNF675 | c.129G>T p.L43= | Splice Region (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100704967; called by muse, mutect2, varscan2
- ZNF773 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99989147; called by muse, mutect2, varscan2
- ZNF804A | c.2452A>T p.R818* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100166911; called by muse, mutect2, varscan2
- ZP4 | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100850626; called by muse, mutect2, varscan2
- BIRC6 | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DUSP14 | c.418T>A p.W140R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- FGFRL1 | c.552G>T p.W184C | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEATR5A | c.3461C>T p.T1154I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); called by muse, mutect2
- HMCN1 | c.15814+4_15814+7del p.X5272_splice | Splice Site (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- IGKV1-27 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- IGKV2D-30 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MYF5 | c.211del p.A71Pfs*26 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel, varscan2
- NDST4 | c.677A>C p.N226T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- NIPAL4 | c.1277del p.P426Lfs*22 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- PLEKHA7 | c.2484_2491del p.F829Sfs*28 | Frame Shift Del (DEL) | VAF 9/112 reads (8%) | called by mutect2, pindel
- PPP1R21 | c.1074del p.Y359Ifs*3 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- RETREG3 | c.246del p.F82Lfs*3 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- STXBP5 | c.895del p.E299Nfs*23 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by pindel, varscan2
- TLL1 | c.1451del p.P484Rfs*2 | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- ULBP2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AGMO | c.249A>T p.R83= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100693833; called by muse, mutect2
- AHNAK2 | c.16140T>C p.S5380= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100316409; called by muse, mutect2, varscan2
- ANOS1 | c.750G>C p.L250= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1275296397, COSV99390620; called by muse, mutect2, varscan2
- APOB | c.10359T>G p.T3453= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs1315058728, COSV99264460; called by muse, mutect2
- ATF6 | c.1212A>G p.R404= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100909081; called by muse, mutect2, varscan2
- BTG1 | c.312C>T p.L104= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99755383; called by muse, mutect2, varscan2
- CACNA1C | c.2418G>A p.L806= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100216859; called by muse, mutect2, varscan2
- CCDC115 | c.306G>T p.R102= | Silent (SNP) | VAF 2/12 reads (17%) | catalogued as COSV52091622; called by muse, mutect2
- CCP110 | c.2781T>A p.A927= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101195237; called by muse, mutect2
- CENPF | c.5247G>A p.L1749= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100871589; called by muse, mutect2, varscan2
- COL14A1 | c.4167C>T p.I1389= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99918471; called by muse, mutect2, varscan2
- DGKB | c.1683G>A p.R561= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV99336291, COSV99337606; called by muse, mutect2, varscan2
- DNAH11 | c.2352G>C p.L784= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100178131; called by muse, mutect2
- DYRK1B | c.1056G>T p.G352= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100546484; called by muse, mutect2, varscan2
- EDN3 | c.300C>T p.F100= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV61110294; called by muse, mutect2, varscan2
- EPS8L2 | c.888G>T p.A296= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100585412; called by muse, mutect2, varscan2
- FGF14 | c.48A>G p.L16= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101085241; called by muse, mutect2, varscan2
- FLNC | c.4962G>A p.L1654= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100367794; called by muse, mutect2, varscan2
- FZD1 | c.1516C>T p.L506= | Silent (SNP) | VAF 10/199 reads (5%) | catalogued as COSV55310224; called by muse, mutect2
- GABRA4 | c.942C>T p.S314= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99973756; called by muse, mutect2, varscan2
- GDF6 | c.1284C>T p.I428= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99747809; called by muse, mutect2, varscan2
- H2AC8 | c.225G>A p.K75= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs563842312, COSV55127248, COSV99773116; called by muse, mutect2, varscan2
- HOXD8 | c.849C>T p.D283= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100497038; called by muse, mutect2
- HS3ST5 | c.39C>A p.L13= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100450524, COSV57133833; called by muse, mutect2
- IFNA6 | c.111C>A p.T37= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV101207018; called by muse, mutect2
- IRX1 | c.558G>A p.K186= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100116355, COSV57361192; called by muse, mutect2, varscan2
- ITGAD | c.1869C>A p.A623= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV101210390; called by muse, mutect2, varscan2
- KLHL34 | c.204C>A p.R68= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1389082426, COSV101069890; called by muse, mutect2, varscan2
- LRRK2 | c.5475C>T p.I1825= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100109583; called by muse, mutect2
- MICAL2 | c.2235A>T p.I745= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV99816942; called by muse, mutect2, varscan2
- MLLT6 | c.777C>T p.P259= | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- NIN | c.87G>T p.G29= | Silent (SNP) | VAF 16/243 reads (7%) | catalogued as rs1007062735, COSV99812453; called by muse, mutect2
- NOD1 | c.2154C>T p.Y718= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs201102944, COSV56111703; called by muse, varscan2
- NOSTRIN | c.762G>A p.K254= (on ENST00000317647 / NM_001039724.4; = p.K176= on NM_052946.3) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100473275; called by muse, mutect2, varscan2
- NRG3 | c.639A>T p.P213= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100930964; called by mutect2, varscan2
- NRP1 | c.1053G>A p.K351= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99587521; called by muse, mutect2, varscan2
- OR10Z1 | c.300G>A p.Q100= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV100778966, COSV63524575; called by muse, mutect2
- OR2G6 | c.375T>G p.A125= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100598062; called by muse, mutect2
- OR2L13 | c.432T>A p.I144= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV100813699; called by muse, mutect2
- OR4A5 | c.699C>A p.A233= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100156999, COSV60522408; called by muse, mutect2, varscan2
- OR51E1 | c.849G>T p.L283= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV101211473; called by muse, mutect2, varscan2
- OR52W1 | c.435T>C p.C145= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100258613; called by muse, mutect2
- OSMR | c.2859G>A p.L953= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV99952879; called by muse, mutect2, varscan2
- PCDH18 | c.2097C>A p.S699= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100787135; called by muse, mutect2
- PCDH18 | c.423C>T p.L141= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100787141; called by muse, mutect2, varscan2
- PHF20 | c.618G>T p.G206= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100179964; called by muse, mutect2, varscan2
- PHLDB2 | c.759C>T p.S253= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV101208459; called by muse, mutect2, varscan2
- PIGP | c.366A>G p.Q122= (on ENST00000464265 / NM_153681.2; = p.Q72= on NM_016430.4) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100308610; called by muse, mutect2, varscan2
- PIK3CD | c.1356G>T p.L452= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100740048; called by muse, mutect2
- PRDX2 | c.466C>T p.L156= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100040125; called by muse, mutect2
- RADIL | c.1578C>G p.L526= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101271314; called by muse, mutect2
- RBM26 | c.744A>G p.V248= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99935934; called by muse, mutect2, varscan2
- RGS9 | c.1839C>A p.P613= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV99287235; called by muse, mutect2, varscan2
- RPS19BP1 | c.390G>A p.Q130= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1279761252; called by muse, mutect2
- SART1 | c.2328G>A p.Q776= | Silent (SNP) | VAF 7/156 reads (4%) | called by muse, mutect2
- SCRG1 | c.144G>A p.L48= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as COSV99633403; called by muse, mutect2, varscan2
- SETX | c.7965G>A p.R2655= | Silent (SNP) | VAF 40/253 reads (16%) | catalogued as COSV99809138; called by muse, mutect2, varscan2
- SH3KBP1 | c.891C>T p.I297= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV101114507; called by muse, mutect2, varscan2
- SLC39A12 | c.1218C>A p.G406= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV101069913; called by muse, mutect2, varscan2
- SPIC | c.399A>T p.V133= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100162880; called by muse, mutect2, varscan2
- SPP1 | c.475C>A p.R159= (on ENST00000395080 / NM_001040058.2; = p.R145= on NM_000582.2) | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV52952154, COSV99420931; called by muse, mutect2
- SYT6 | c.849C>A p.T283= (on ENST00000610222 / NM_001366225.1; = p.T198= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV101059622, COSV65774192; called by muse, mutect2, varscan2
- TARS1 | c.1026T>C p.S342= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99465646; called by muse, mutect2
- TECPR2 | c.60C>A p.L20= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- TLL1 | c.1251A>T p.S417= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99286623; called by muse, mutect2
- TM9SF3 | c.816T>C p.Y272= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100951827; called by muse, mutect2, varscan2
- TMCC2 | c.1161G>T p.V387= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100319214; called by muse, mutect2, varscan2
- TSHZ2 | c.912T>A p.P304= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100295639; called by muse, mutect2, varscan2
- TTYH3 | c.1122G>A p.V374= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV99349610; called by muse, mutect2, varscan2
- WDR55 | c.105C>T p.I35= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100845561; called by muse, mutect2
- WHRN | c.526C>T p.L176= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99469990; called by muse, mutect2, varscan2
- ZFHX4 | c.3916C>A p.R1306= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs748037378, COSV50909309, COSV99259522; called by mutect2, varscan2
- ZNF793 | c.591C>T p.F197= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV71324925, COSV71325092; called by muse, mutect2
- ZNF831 | c.229C>T p.L77= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100925891; called by muse, mutect2, varscan2
- ZSCAN30 | c.1308T>A p.T436= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99734759; called by muse, mutect2, varscan2
- ATP6AP1L | n.1805G>T | RNA (SNP) | VAF 9/54 reads (17%) | catalogued as COSV101205109; called by muse, mutect2, varscan2
- CCDC28A | c.-170A>C | 5'UTR (SNP) | VAF 18/145 reads (12%) | catalogued as COSV100236373; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85563C>A | Intron (SNP) | VAF 4/51 reads (8%) | catalogued as COSV72282575; called by muse, mutect2
- OR52A4P | chr11:5121060 G>T | 3'Flank (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
